Gene-level copy-number profile of tumor specimen TCGA-HQ-A2OF-01A from TCGA case TCGA-HQ-A2OF, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Dome of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 52.1 years (19,016 days).
Specimen TCGA-HQ-A2OF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.fde4bda2-fafb-4d93-aa55-a7cf22dadae3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HQ-A2OF-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bfcf3571-7885-4b42-b7a0-a27a857f9aef

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 874; copy number 2: 26,546; copy number 3: 19,299; copy number 4: 9,985; copy number 5: 1,092; copy number 6: 1,631; copy number 7: 17; copy number 8: 8; copy number 9: 76; copy number 10: 61; copy number 12: 141; copy number 13: 50; copy number 16: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HQ-A2OF-01A-11D-A26L-01): tumor purity 0.93, ploidy 2.95, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,113 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:41,032,892–67,849,338, 411 genes, copy number 6 (broad region; genes not listed).
- chr8:70,669,369–72,357,815, 15 genes, copy number 6 (within-gene range 4–6): AC015687.1, Y_RNA, AC022858.1, EYA1, TRAPPC2P2, AC009446.1, AC104012.1, U8, MSC-AS1, MSC, RPS20P20, TRPA1, AC078906.1, AC022905.1, RNA5SP271.
- chr8:73,420,369–73,747,708, 1 gene, copy number 6 (within-gene range 4–6): STAU2.
- chr8:73,590,574–145,066,685, 1,118 genes, copy number 6 (broad region; genes not listed).
- chr16:8,508,069–29,731,404, 598 genes, copy number 5 (broad region; genes not listed).
- chr17:35,963,488–40,799,959, 205 genes, copy number 6–12 (broad region; genes not listed).
- chr17:45,894,551–47,624,665, 50 genes, copy number 13 (within-gene range 2–13): MAPT, MAPT-IT1, CR936218.2, Metazoa_SRP, STH, KANSL1, CR936218.1, KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1, ARL17B, LRRC37A, RN7SL656P, NSFP1, RDM1P2, LRRC37A2, ARL17A, RN7SL199P, FAM215B, NSF, RPS7P11, WNT3, WNT9B, LINC01974, AC005670.1, RNU6ATAC3P, GOSR2, AC005670.2, MIR5089, RPRML, LRRC37A17P, AC005670.3, RN7SL270P, CDC27, AC002558.1, AC002558.3, AC002558.2, MYL4, ITGB3, AC068234.1, RNU7-186P, AC068234.2, THCAT158, EFCAB13, AC040934.1, MRPL45P2, NPEPPS, Y_RNA.
- chr17:47,807,372–53,106,358, 201 genes, copy number 5–16 (broad region; genes not listed).
- chr17:53,353,427–53,439,721, 3 genes, copy number 10: AC005341.1, AC090079.1, AC090079.2.
- chr20:2,536,607–8,999,100, 142 genes, copy number 5–6 (broad region; genes not listed).
- chr20:18,782,424–20,002,459, 14 genes, copy number 5 (within-gene range 4–5): EEF1A1P34, LINC00652, LINC00653, SCP2D1-AS1, SCP2D1, AL135936.1, AL136090.2, SLC24A3, AL136090.1, SLC24A3-AS1, AL121830.1, AL121761.1, RIN2, RPL12P12.
- chr20:36,507,702–46,736,347, 267 genes, copy number 5–9 (broad region; genes not listed).
- chr20:55,607,852–59,032,345, 88 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 36. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
